Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3909, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3909-01A (Primary Tumor).

Diagnosis

Rectosigmoid resected material with an ulcerated, moderately differentiated adenocarcinoma of the colorectal type, located 3 cm from the aboral resection margin, 4 cm in diameter, with infiltration of the perirectal fatty tissue, carcinomatous lymphangitis alongside the tumor, as well as three local lymph node metastases. Tumor-free colon resection margins. Tumor-free mesenteric resection margin. Tumor-free circumferential resection margin. Diverticulosa coli in addition.

Tumor stage: pT3, pN1 (3/35), pMX; G2, L1, V0, local R0.

Source: NCI Genomic Data Commons file ba284dea-ccb4-44a8-8ffe-9f9a6ed1d3b2 (TCGA-AG-3909.A36E0E59-3AE5-4606-ACBB-773BB0E11DA8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).